Gene-level copy-number profile of tumor specimen MP2PRT-PARMGR-TMP1-A from MP2PRT case MP2PRT-PARMGR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,820 days).
Specimen MP2PRT-PARMGR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec0e7992-1ea1-4f35-95c3-95370bad3def.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARMGR-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/73588daa-dec0-4276-aa9d-a7da7acca430

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 3,791; copy number 2: 55,007; copy number 3: 7.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,040,224–89,085,787, 4 genes (within-gene range 0–1): IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15.
- chr2:89,192,500–89,213,928, 4 genes (within-gene range 0–1): IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27.
- chr2:89,252,211–89,275,787, 4 genes: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34.
- chr2:89,989,987–90,022,185, 5 genes: IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21.
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–1): IGKV2D-14.
- chr2:90,179,889–90,221,384, 4 genes: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–1): PRB1.
- chr14:22,422,371–22,497,718, 31 genes (within-gene range 0–2): TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:105,881,034–106,012,420, 36 genes (within-gene range 0–2): IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 935. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
